Somatic mutation profile of tumor specimen TCGA-V1-A8WW-01A (aliquot TCGA-V1-A8WW-01A-11D-A377-08) from TCGA case TCGA-V1-A8WW, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8WW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44caf44d-34c2-4df8-812e-bb35288dbdb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8WW-10A (Blood Derived Normal), aliquot TCGA-V1-A8WW-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fc70ce5-8729-4dff-94c5-2696d20d904a

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Nonsense Mutation 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 20/31 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs794727165, CM064027, CM1210297, COSV100256832; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.10367G>A p.G3456D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs760279615, COSV52143939, COSV99999430; called by muse, mutect2, varscan2
- ATF7IP | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 72/104 reads (69%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV99661155; called by muse, varscan2
- ATF7IP | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 110/176 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV99661157; called by muse, varscan2
- CD83 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100997698; called by muse, mutect2, varscan2
- DGKD | c.2908C>T p.P970S (on ENST00000264057 / NM_152879.3; = p.P926S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV99895269; called by muse, mutect2, varscan2
- FANCB | c.1831A>G p.K611E | Missense Mutation (SNP) | VAF 84/97 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60762546; called by muse, mutect2, varscan2
- GIGYF2 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101003828, COSV65249132; called by muse, mutect2, varscan2
- ITGA1 | c.1893A>T p.K631N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs199962878, COSV99250604; called by muse, mutect2
- KIAA1549L | c.5342G>A p.R1781H (on ENST00000321505; = p.R2078H on NM_012194.3) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs770312233, COSV58585361; called by muse, mutect2, varscan2
- KRT79 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100398276; called by muse, mutect2, varscan2
- MAN2B1 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55472202; called by muse, mutect2, varscan2
- MUC17 | c.3796A>T p.T1266S | Missense Mutation (SNP) | VAF 115/439 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100071440; called by muse, mutect2, varscan2
- NLRP13 | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV100738009; called by muse, mutect2
- OBSCN | c.11225C>T p.P3742L | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs774737718, COSV52740001; called by muse, mutect2, varscan2
- POMC | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775998713, COSV53034904; called by muse, mutect2, varscan2
- SIK2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs200775925, COSV100515922; called by muse, mutect2, varscan2
- SIRT1 | c.1040T>A p.I347K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99281576; called by muse, mutect2, varscan2
- SLC23A2 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs761285478, COSV100594753, COSV100595265; called by muse, mutect2, varscan2
- SLC27A4 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100307023; called by muse, mutect2, varscan2
- SLC28A1 | c.876+1G>T p.X292_splice | Splice Site (SNP) | VAF 32/71 reads (45%) | catalogued as COSV99722473; called by muse, mutect2
- SMIM21 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs148196575; called by mutect2, varscan2
- TYMS | c.680T>A p.I227N | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99200948; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3521C>T p.A1174V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99511397; called by muse, mutect2, varscan2
- IGKV1D-13 | c.258C>T p.G86= | Silent (SNP) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- ITGAL | c.1206C>A p.G402= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1438187475, COSV100776042; called by muse, mutect2, varscan2
- MTOR | c.5679C>G p.S1893= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100815685; called by muse, mutect2, varscan2
- RGS11 | c.708G>T p.A236= (on ENST00000397770 / NM_183337.3; = p.A215= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs944418493, COSV51451613, COSV51452682, COSV99395600; called by muse, mutect2, varscan2
- ZNF286A | c.837T>G p.S279= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV101224718; called by muse, mutect2, varscan2
- IGKV1-13 | n.259C>T | RNA (SNP) | VAF 24/155 reads (15%) | called by mutect2, varscan2
